Somatic mutation profile of cancer-model specimen HCM-BROD-1122-C49-85B (Adherent Cell Line, passage 8; aliquot HCM-BROD-1122-C49-85B-01D-A88G-36), derived from the primary tumor of HCMI case HCM-BROD-1122-C49, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: female; Vital status: Alive; Primary diagnosis: Clear cell sarcoma, NOS; Tissue or organ of origin: Connective, subcutaneous and other soft tissues, NOS; Tumor grade: GX; Age at diagnosis: 34.7 years (12,656 days).
Specimen HCM-BROD-1122-C49-85B: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Adherent Cell Line; Preservation method: Frozen; Passage count: 8.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 9021a2f3-d351-4373-9401-ee9840b13cd6.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen HCM-BROD-1122-C49-10A (Blood Derived Normal), aliquot HCM-BROD-1122-C49-10A-01D-A88G-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/14f12573-c76d-4b99-bef8-9bb3279aa8f9

The open-access MAF lists 23 somatic variants for this specimen: 19 protein-altering or splice-affecting, 3 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 17, Silent 3, Intron 1, Nonsense Mutation 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ADAMTS12 | c.3775C>A p.P1259T | Missense Mutation (SNP) | VAF 32/564 reads (6%) | SIFT tolerated (0.13); PolyPhen benign (0); catalogued as rs1159095192, COSV61283633; called by muse, mutect2
- FOXK2 | c.1949C>T p.P650L | Missense Mutation (SNP) | VAF 37/354 reads (10%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.115); catalogued as rs751159078; called by muse, mutect2, varscan2
- TNFRSF11B | c.68C>T p.T23M | Missense Mutation (SNP) | VAF 47/215 reads (22%) | SIFT deleterious (0.02); PolyPhen benign (0.164); catalogued as rs1305087823, COSV52069074, COSV52069909; called by muse, mutect2, varscan2
- UNC5C | c.631G>A p.V211I | Missense Mutation (SNP) | VAF 34/340 reads (10%) | SIFT tolerated (0.14); PolyPhen benign (0.195); catalogued as rs763516412; called by muse, mutect2
- XKR9 | c.899G>A p.G300E | Missense Mutation (SNP) | VAF 25/248 reads (10%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.844); catalogued as rs1563458544; called by muse, mutect2, varscan2
- ZNF85 | c.476C>A p.S159* | Nonsense Mutation (SNP) | VAF 28/386 reads (7%) | catalogued as COSV60215344; called by muse, mutect2
- ANKRD13C | c.753A>G p.I251M | Missense Mutation (SNP) | VAF 20/176 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); called by muse, mutect2, varscan2
- ASCC1 | c.445G>A p.D149N (on ENST00000342444 / NM_001369085.1; = p.D121N on NM_001198798.2 and 8 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 99/402 reads (25%) | SIFT tolerated (0.09); PolyPhen benign (0.376); called by muse, mutect2, varscan2
- DMPK | c.1511del p.R504Pfs*10 | Frame Shift Del (DEL) | VAF 43/392 reads (11%) | called by mutect2, pindel, varscan2
- HAP1 | c.894G>T p.K298N | Missense Mutation (SNP) | VAF 34/370 reads (9%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.559); called by muse, mutect2
- IL17RB | c.1072C>T p.H358Y | Missense Mutation (SNP) | VAF 11/303 reads (4%) | SIFT tolerated (0.28); PolyPhen benign (0.007); called by muse, mutect2
- MUC2 | c.1144T>A p.C382S | Missense Mutation (SNP) | VAF 58/583 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- OR10C1 | c.161C>T p.A54V (on ENST00000622521; = p.A52V on NM_013941.3) | Missense Mutation (SNP) | VAF 64/582 reads (11%) | SIFT deleterious (0.01); PolyPhen benign (0.096); called by muse, varscan2
- RPS24 | c.22C>G p.R8G | Missense Mutation (SNP) | VAF 73/264 reads (28%) | SIFT deleterious (0.02); PolyPhen benign (0); called by muse, mutect2, varscan2
- SHROOM2 | c.1837G>T p.D613Y | Missense Mutation (SNP) | VAF 172/782 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); called by muse, mutect2, varscan2
- TEX15 | c.7298A>C p.N2433T (on ENST00000256246; = p.N2816T on NM_001350162.2) | Missense Mutation (SNP) | VAF 125/373 reads (34%) | SIFT tolerated (0.08); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- TMEM132D | c.1714T>C p.Y572H | Missense Mutation (SNP) | VAF 62/686 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.919); called by muse, mutect2
- TRIM62 | c.976C>A p.P326T | Missense Mutation (SNP) | VAF 48/606 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- TRPM7 | c.2774A>G p.N925S | Missense Mutation (SNP) | VAF 78/239 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- FLNB | c.2208C>T p.I736= | Silent (SNP) | VAF 20/228 reads (9%) | catalogued as rs781155126; called by muse, mutect2
- IRAK2 | c.1671C>T p.P557= | Silent (SNP) | VAF 144/488 reads (30%) | called by muse, mutect2, varscan2
- LRRC4B | c.414G>A p.T138= | Silent (SNP) | VAF 46/598 reads (8%) | catalogued as rs1476394899, COSV65350181; called by muse, mutect2
- BRD8 | c.643-558C>G | Intron (SNP) | VAF 103/334 reads (31%) | called by muse, mutect2, varscan2
